Somatic mutation profile of tumor specimen TCGA-DU-A5TU-01A (aliquot TCGA-DU-A5TU-01A-11D-A289-08) from TCGA case TCGA-DU-A5TU, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 62.5 years (22,811 days).
Specimen TCGA-DU-A5TU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73d6222f-e4ab-41a4-8d59-75451423457c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A5TU-10A (Blood Derived Normal), aliquot TCGA-DU-A5TU-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be45f23d-fa2d-49a4-b79d-873cdafc4ac8

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 60/76 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1555526268, CM971503, COSV52676850, COSV52715987, COSV52740951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 48/110 reads (44%) | catalogued as COSV62349001; called by muse, mutect2, varscan2
- ARHGAP30 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV63516909, COSV63517871; called by muse, mutect2, varscan2
- ATRX | c.6797del p.L2266* | Frame Shift Del (DEL) | VAF 41/190 reads (22%) | catalogued as COSV100971361; called by mutect2, pindel, varscan2
- CARD11 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62754862; called by muse, mutect2, varscan2
- CD1B | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); catalogued as rs1188010034, COSV63804456; called by muse, mutect2, varscan2
- DCAF12L2 | c.1004G>C p.R335P | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63580452, COSV63582250; called by muse, mutect2
- DNAH3 | c.9724A>G p.I3242V | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99768104; called by muse, mutect2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- FKBP6 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52720771; called by muse, mutect2
- GAS2L1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as rs766729816, COSV53330574; called by muse, mutect2, varscan2
- GJC3 | c.725A>C p.K242T | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); catalogued as COSV57210439; called by muse, mutect2, varscan2
- HCFC1 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as COSV60073500; called by muse, mutect2, varscan2
- KRT31 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV52435792; called by muse, mutect2, varscan2
- MAGEA8 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV54064305, COSV54064543; called by muse, mutect2, varscan2
- MAP3K1 | c.3250G>A p.D1084N | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV68123441; called by muse, mutect2
- MORC1 | c.724T>G p.S242A | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.027); catalogued as COSV51722154, COSV99225382; called by muse, mutect2, varscan2
- NFATC2 | c.1535+1G>A p.X512_splice | Splice Site (SNP) | VAF 29/134 reads (22%) | catalogued as rs200028027, COSV65357269; called by muse, mutect2, varscan2
- PLCE1 | c.2673G>T p.L891F | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV53355144; called by muse, mutect2, varscan2
- RSAD2 | c.734G>A p.W245* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV65908446; called by muse, mutect2, varscan2
- SLCO2A1 | c.740T>C p.V247A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs752160678, COSV60486602; called by muse, mutect2, varscan2
- TDRD6 | c.4009A>G p.R1337G | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.725); catalogued as COSV100287769; called by muse, mutect2
- TEX101 | c.653G>A p.R218Q (on ENST00000598265 / NM_001130011.3; = p.R236Q on NM_031451.4) | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs765107389, COSV53661613; called by muse, mutect2, varscan2
- TTN | c.19304G>T p.S6435I (on ENST00000591111; = p.S5508I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/130 reads (5%) | PolyPhen probably damaging (0.949); catalogued as COSV100617459; called by muse, mutect2
- TXNDC2 | c.485G>A p.G162D (on ENST00000306084 / NM_001098529.2; = p.G95D on NM_032243.6) | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV60153908; called by muse, varscan2
- WDR81 | c.4450A>G p.M1484V (on ENST00000409644 / NM_001163809.2; = p.M433V on NM_152348.4) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV58484149; called by muse, mutect2, varscan2
- ZNF711 | c.1003A>G p.T335A | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1451128176, COSV52155705; called by muse, mutect2, varscan2
- BTK | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTN3 | c.2676C>T p.S892= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV59749173; called by muse, mutect2, varscan2
- ADSS2 | c.960A>G p.L320= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV63695360; called by muse, mutect2, varscan2
- AMER2 | c.1884A>G p.Q628= | Silent (SNP) | VAF 73/190 reads (38%) | catalogued as COSV63438256; called by muse, mutect2, varscan2
- CRYBB2 | c.207C>T p.G69= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as rs768854542, COSV68005530; called by muse, mutect2, varscan2
- ENTPD7 | c.1617T>C p.H539= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV65112459; called by muse, mutect2, varscan2
- FBN1 | c.4293C>T p.C1431= | Silent (SNP) | VAF 72/182 reads (40%) | catalogued as rs112375043, CM117722, COSV57313267; ClinVar: likely benign; called by muse, mutect2, varscan2
- JADE1 | c.1038C>T p.G346= | Silent (SNP) | VAF 61/177 reads (34%) | catalogued as COSV56906933; called by muse, mutect2, varscan2
- KIAA1109 | c.2289A>G p.E763= | Silent (SNP) | VAF 66/175 reads (38%) | catalogued as rs779072924, COSV52677756; called by muse, mutect2, varscan2
- RGS6 | c.978C>T p.S326= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV100666373; called by muse, mutect2
- SLC39A4 | c.1272G>C p.L424= (on ENST00000301305 / NM_001374839.1; = p.L399= on NM_017767.3) | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV52779453; called by muse, mutect2, varscan2
- SLC7A7 | c.42G>A p.E14= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs1352517286, COSV53539814; called by muse, mutect2, varscan2
- MIR892B | n.66G>T | RNA (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
